Somatic mutation profile of tumor specimen TCGA-BQ-5892-01A (aliquot TCGA-BQ-5892-01A-11D-1589-08) from TCGA case TCGA-BQ-5892, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 51.4 years (18,785 days).
Specimen TCGA-BQ-5892-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1ca455e-0550-4962-bf21-3f59189c12c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-5892-11A (Solid Tissue Normal), aliquot TCGA-BQ-5892-11A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef23bd71-f6e7-48ad-822b-adab1034ed51

The open-access MAF lists 63 somatic variants for this specimen: 55 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 36, Frame Shift Del 11, Silent 8, Nonsense Mutation 3, Splice Site 2, Frame Shift Ins 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.499C>G p.R167G | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs5030820, CM941383, CM941384, HX040002, COSV56545406, COSV56546550, COSV56572034; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALPK1 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV51590842, COSV99454381; called by muse, mutect2, varscan2
- APBB2 | c.832A>T p.T278S | Missense Mutation (SNP) | VAF 86/313 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as COSV55960918; called by muse, mutect2, varscan2
- BAP1 | c.29G>A p.S10N | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56234612, COSV56234931, COSV56236530; called by muse, mutect2, varscan2
- BDP1 | c.2302C>T p.Q768* | Nonsense Mutation (SNP) | VAF 39/131 reads (30%) | catalogued as rs749682004, COSV62434187; called by muse, mutect2, varscan2
- C10orf90 | c.693G>C p.E231D | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV52962888; called by muse, mutect2, varscan2
- CACHD1 | c.3197G>A p.G1066E | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51559231; called by muse, mutect2
- CCAR2 | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV52386361; called by muse, mutect2, varscan2
- CHD8 | c.5513del p.K1838Rfs*53 (on ENST00000646647 / NM_001170629.2; = p.K1559Rfs*53 on NM_020920.4) | Frame Shift Del (DEL) | VAF 22/84 reads (26%) | catalogued as COSV63037008; called by mutect2, pindel, varscan2
- CNOT1 | c.3931A>C p.N1311H | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV55321691; called by muse, mutect2, varscan2
- DDX47 | c.374T>C p.V125A | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV61912025; called by muse, mutect2, varscan2
- ECI2 | c.502-2A>T p.X168_splice (on ENST00000380118 / NM_206836.3; = p.X138_splice on NM_006117.2) | Splice Site (SNP) | VAF 50/174 reads (29%) | catalogued as COSV60988731; called by muse, mutect2, varscan2
- ERG | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.09); catalogued as rs552037654, COSV55726607; called by muse, mutect2
- FBXO34 | c.1243C>G p.P415A | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV58256667; called by muse, mutect2, varscan2
- FMO1 | c.541A>T p.I181L | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs752154064, COSV61447547; called by muse, mutect2, varscan2
- GAS7 | c.673C>T p.Q225* (on ENST00000432992 / NM_201433.2; = p.Q85* on NM_003644.3) | Nonsense Mutation (SNP) | VAF 16/348 reads (5%) | catalogued as COSV60442784; called by muse, mutect2
- JAG1 | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV54761992; called by muse, mutect2, varscan2
- KIAA1109 | c.1526G>C p.S509T | Missense Mutation (SNP) | VAF 60/251 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV52689607; called by muse, mutect2, varscan2
- MLKL | c.399G>C p.W133C | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.087); catalogued as COSV58206369; called by muse, mutect2, varscan2
- MRPL10 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 77/161 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV50114521; called by muse, mutect2, varscan2
- MUC16 | c.35152G>C p.V11718L | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV67454683, COSV67489089; called by muse, mutect2, varscan2
- MUC16 | c.5977G>T p.E1993* | Nonsense Mutation (SNP) | VAF 7/109 reads (6%) | catalogued as COSV67489092, COSV67502498; called by muse, mutect2
- MYO1D | c.2776G>A p.D926N | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59022088; called by muse, mutect2, varscan2
- NIM1K | c.652A>G p.S218G | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58145193; called by muse, mutect2, varscan2
- NT5C1B | c.307C>G p.Q103E (on ENST00000359846 / NM_001199086.2; = p.Q43E on NM_033253.4) | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.106); catalogued as COSV58398610; called by muse, mutect2, varscan2
- OR52B2 | c.583A>T p.T195S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); catalogued as COSV73209562; called by muse, mutect2, varscan2
- RORB | c.1162G>A p.E388K (on ENST00000396204 / NM_001365023.1; = p.E377K on NM_006914.4) | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as COSV65335657, COSV65338414, COSV65339472; called by muse, mutect2, varscan2
- SHC2 | c.1540A>G p.T514A | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV52749037; called by muse, mutect2, varscan2
- SKIV2L | c.3577G>A p.E1193K | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61714920; called by muse, mutect2, varscan2
- SLC13A5 | c.1056-1G>C p.X352_splice | Splice Site (SNP) | VAF 16/62 reads (26%) | catalogued as rs113208940, COSV53424875; called by muse, mutect2, varscan2
- SON | c.114T>G p.N38K | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV51669152; called by muse, mutect2, varscan2
- SON | c.1324T>G p.S442A | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.432); catalogued as COSV51669182; called by muse, mutect2, varscan2
- SPATA31A3 | c.3314C>T p.P1105L | Missense Mutation (SNP) | VAF 158/297 reads (53%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.7); catalogued as rs1211397936; called by muse, mutect2, varscan2
- SRSF5 | c.808A>G p.S270G | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT tolerated, low confidence (0.83); PolyPhen possibly damaging (0.483); catalogued as COSV53683804; called by muse, mutect2, varscan2
- SUCO | c.1976T>G p.L659R | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV55270441; called by muse, mutect2, varscan2
- TELO2 | c.1824G>T p.Q608H | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51980779; called by muse, mutect2, varscan2
- TEX15 | c.2464A>G p.I822V (on ENST00000256246; = p.I1205V on NM_001350162.2) | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.173); catalogued as COSV56352565; called by muse, mutect2, varscan2
- TMEM81 | c.404T>G p.F135C | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52706642; called by muse, mutect2, varscan2
- UBE2L3 | c.365G>C p.R122P | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60536492, COSV60537643; called by muse, mutect2, varscan2
- UBTF | c.665C>G p.T222S | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV57188151; called by muse, mutect2, varscan2
- UTP14A | c.384C>T p.I128= | Splice Region (SNP) | VAF 103/167 reads (62%) | catalogued as COSV64087793; called by muse, mutect2, varscan2
- ZNF44 | c.521C>G p.T174S (on ENST00000356109 / NM_001164276.2; = p.T126S on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as COSV61136188; called by muse, mutect2, varscan2
- ZNF544 | c.2113G>A p.V705M | Missense Mutation (SNP) | VAF 84/310 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.218); catalogued as COSV54138234; called by muse, mutect2
- ATXN3L | c.806_807del p.T269Ifs*19 | Frame Shift Del (DEL) | VAF 183/385 reads (48%) | called by mutect2, pindel, varscan2
- CADPS2 | c.1777dup p.Y593Lfs*2 | Frame Shift Ins (INS) | VAF 34/140 reads (24%) | called by mutect2, pindel, varscan2
- CEP250 | c.1823dup p.L608Ffs*5 | Frame Shift Ins (INS) | VAF 21/77 reads (27%) | called by mutect2, pindel, varscan2
- GPR155 | c.28_32del p.L10Hfs*18 | Frame Shift Del (DEL) | VAF 45/152 reads (30%) | called by mutect2, pindel, varscan2
- HAUS3 | c.144_147del p.E49Rfs*23 | Frame Shift Del (DEL) | VAF 48/176 reads (27%) | called by pindel, varscan2
- LRRC8E | c.118del p.V40Sfs*8 | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | called by mutect2, pindel, varscan2
- MAML1 | c.958_976del p.G320Ffs*9 | Frame Shift Del (DEL) | VAF 30/96 reads (31%) | called by mutect2, pindel, varscan2
- MTCH2 | c.406del p.L136Sfs*8 | Frame Shift Del (DEL) | VAF 19/66 reads (29%) | called by mutect2, pindel, varscan2
- RCAN3 | c.107del p.L36Wfs*4 | Frame Shift Del (DEL) | VAF 18/98 reads (18%) | called by mutect2, pindel, varscan2
- SAR1B | c.81del p.K27Nfs*19 | Frame Shift Del (DEL) | VAF 34/160 reads (21%) | called by mutect2, pindel, varscan2
- SQLE | c.849del p.A284Qfs*28 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by pindel, varscan2
- ZNF225 | c.1563del p.F521Lfs*17 | Frame Shift Del (DEL) | VAF 12/118 reads (10%) | called by mutect2, varscan2
- ANP32D | c.237C>T p.G79= | Silent (SNP) | VAF 35/103 reads (34%) | catalogued as COSV56980911; called by muse, mutect2, varscan2
- CPO | c.738C>T p.Y246= | Silent (SNP) | VAF 15/239 reads (6%) | catalogued as rs768140084, COSV55941327; called by muse, mutect2
- KIF21B | c.846G>T p.R282= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV59764830; called by muse, mutect2, varscan2
- NUP160 | c.3210T>G p.A1070= | Silent (SNP) | VAF 31/132 reads (23%) | catalogued as COSV65855749; called by muse, mutect2, varscan2
- NYAP1 | c.1659C>T p.A553= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV55721386; called by muse, mutect2, varscan2
- SCGN | c.807T>C p.C269= | Silent (SNP) | VAF 53/178 reads (30%) | catalogued as COSV58546966; called by muse, mutect2, varscan2
- SHCBP1L | c.393G>A p.L131= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV62356809; called by muse, mutect2, varscan2
- ZNF691 | c.558C>A p.L186= (on ENST00000372502; = p.L155= on NM_015911.3) | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV65289638; called by muse, mutect2, varscan2
